Somatic mutation profile of tumor specimen TCGA-ET-A3DR-01A (aliquot TCGA-ET-A3DR-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.2 years (15,404 days).
Specimen TCGA-ET-A3DR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ec98d64-12ce-41d2-8d36-fc2c5e57e571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DR-10A (Blood Derived Normal), aliquot TCGA-ET-A3DR-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb70881-e56c-4d57-ad22-b516161f5829

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF3 | c.1340A>C p.H447P (on ENST00000311519 / NM_001145168.1; = p.H248P on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV61049050; called by muse, mutect2, varscan2
- JAKMIP1 | c.1087del p.E363Kfs*5 | Frame Shift Del (DEL) | VAF 43/161 reads (27%) | catalogued as COSV51532343; called by mutect2, pindel, varscan2
- KLHL4 | c.2053A>G p.N685D | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV64139658; called by muse, mutect2, varscan2
- KMT2E | c.557-1G>T p.X186_splice | Splice Site (SNP) | VAF 71/210 reads (34%) | catalogued as COSV57570277; called by muse, mutect2, varscan2
- PRKG1 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.025); catalogued as COSV64767203; called by muse, mutect2, varscan2
- TMEM94 | c.2168A>G p.Y723C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.995); catalogued as COSV58593414; called by muse, mutect2, varscan2
- XPO4 | c.1961A>G p.E654G | Missense Mutation (SNP) | VAF 27/347 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55004858; called by muse, mutect2
- MED12L | c.5820C>T p.G1940= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV56370687; called by muse, mutect2, varscan2
- NUP210L | c.1047C>T p.C349= | Silent (SNP) | VAF 13/171 reads (8%) | catalogued as COSV55142907; called by muse, mutect2
- SASH1 | c.918C>G p.L306= | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as COSV66559383; called by muse, mutect2, varscan2
